Somatic mutation profile of tumor specimen C3N-00957-01 (aliquot CPT0089720009_1) from CPTAC case C3N-00957, project CPTAC-3 (Pancreas — Ductal and Lobular Neoplasms). Sex at birth: male; Vital status: Alive; Primary diagnosis: Infiltrating duct carcinoma, NOS; Tissue or organ of origin: Pancreas, NOS; AJCC pathologic stage: Stage IIA; Tumor grade: G2; Age at diagnosis: 74.2 years (27,089 days).
Specimen C3N-00957-01: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Biospecimen anatomic site: Pancreas; Preservation method: Snap Frozen.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 1f213b20-a0d6-4735-b8c3-b89b4279023d.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen C3N-00957-31 (Blood Derived Normal), aliquot CPT0091380002; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/4da8f0a5-058f-4508-b86f-4ec18a2fc70a

The open-access MAF lists 46 somatic variants for this specimen: 35 protein-altering or splice-affecting, 7 silent, 4 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 31, Silent 7, Intron 4, Nonsense Mutation 4.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- KRAS | c.35G>T p.G12V | Missense Mutation (SNP) | VAF 38/666 reads (6%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.972); catalogued as rs121913529, COSV55497369, COSV55497419, COSV55497479; ClinVar: likely pathogenic / pathogenic; called by muse, mutect2
- TP53 | c.493C>T p.Q165* | Nonsense Mutation (SNP) | VAF 59/640 reads (9%) | hotspot (GDC flag); catalogued as rs730882001, COSV52677910, COSV52844585, COSV53637782; ClinVar: pathogenic; called by muse, mutect2
- C10orf71 | c.2906G>A p.R969Q | Missense Mutation (SNP) | VAF 20/242 reads (8%) | SIFT tolerated (0.54); PolyPhen benign (0.084); catalogued as rs546401015; called by muse, mutect2
- CACNA1A | c.286G>A p.E96K | Missense Mutation (SNP) | VAF 22/563 reads (4%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.988); catalogued as COSV64197989; called by muse, mutect2
- CCL21 | c.136C>T p.R46C | Missense Mutation (SNP) | VAF 22/530 reads (4%) | SIFT deleterious (0); PolyPhen probably damaging (0.963); catalogued as rs1453433779; called by muse, mutect2
- CROCC2 | c.851C>T p.T284M | Missense Mutation (SNP) | VAF 17/476 reads (4%) | SIFT tolerated (0.22); PolyPhen benign (0.057); catalogued as rs889297637; called by muse, mutect2
- CSMD3 | c.4408C>T p.R1470* (on ENST00000297405 / NM_001363185.1; = p.R1366* on NM_052900.3) | Nonsense Mutation (SNP) | VAF 37/781 reads (5%) | catalogued as COSV52262902; called by muse, mutect2
- CUX2 | c.579G>T p.Q193H | Missense Mutation (SNP) | VAF 40/468 reads (9%) | SIFT tolerated (0.07); PolyPhen benign (0); catalogued as COSV55628920; called by muse, mutect2
- LRRC4C | c.1432C>T p.P478S | Missense Mutation (SNP) | VAF 21/422 reads (5%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.829); catalogued as COSV53421396; called by muse, mutect2
- MED12L | c.748G>A p.E250K | Missense Mutation (SNP) | VAF 39/459 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.972); catalogued as COSV56368485, COSV99853076; called by muse, mutect2
- MKI67 | c.4796G>A p.G1599D | Missense Mutation (SNP) | VAF 60/762 reads (8%) | SIFT tolerated (0.89); PolyPhen benign (0.03); catalogued as rs921602539; called by muse, mutect2
- POM121L12 | c.778G>A p.A260T | Missense Mutation (SNP) | VAF 30/418 reads (7%) | SIFT tolerated, low confidence (0.53); PolyPhen benign (0.025); catalogued as rs202031574, COSV68692498; called by muse, mutect2
- TAF1L | c.2672C>T p.T891M | Missense Mutation (SNP) | VAF 74/902 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); catalogued as rs1183499757, COSV54256582, COSV99645119; called by muse, mutect2
- ASCL4 | c.95C>T p.P32L | Missense Mutation (SNP) | VAF 22/690 reads (3%) | SIFT deleterious (0.04); PolyPhen benign (0.287); called by muse, mutect2
- CDC42EP3 | c.409C>T p.P137S | Missense Mutation (SNP) | VAF 28/567 reads (5%) | SIFT tolerated (0.13); PolyPhen benign (0); called by muse, mutect2
- COL9A1 | c.2447G>A p.R816H | Missense Mutation (SNP) | VAF 28/576 reads (5%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); called by muse, mutect2
- DUSP13 | c.455T>C p.L152P | Missense Mutation (SNP) | VAF 30/666 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2
- EPHB3 | c.2613G>A p.M871I | Missense Mutation (SNP) | VAF 40/476 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.981); called by muse, mutect2
- EPPK1 | c.5936G>A p.R1979K | Missense Mutation (SNP) | VAF 34/319 reads (11%) | SIFT tolerated (0.28); PolyPhen benign (0); called by muse, mutect2, varscan2
- GOSR1 | c.326A>G p.Q109R | Missense Mutation (SNP) | VAF 42/440 reads (10%) | SIFT deleterious (0.05); PolyPhen benign (0.08); called by muse, mutect2
- HIGD1C | c.262A>T p.R88* | Nonsense Mutation (SNP) | VAF 30/568 reads (5%) | called by muse, mutect2
- IFITM2 | c.176G>T p.W59L | Missense Mutation (SNP) | VAF 26/916 reads (3%) | SIFT deleterious (0.01); PolyPhen benign (0.443); called by muse, mutect2
- KCNMA1 | c.1208C>T p.A403V | Missense Mutation (SNP) | VAF 32/1068 reads (3%) | SIFT tolerated (0.7); PolyPhen benign (0.003); called by muse, mutect2
- LAMA5 | c.2698A>G p.N900D | Missense Mutation (SNP) | VAF 19/298 reads (6%) | SIFT tolerated (0.37); PolyPhen benign (0.015); called by muse, mutect2
- NHSL1 | c.2135T>A p.L712Q | Missense Mutation (SNP) | VAF 13/189 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2
- NYX | c.625C>T p.R209C | Missense Mutation (SNP) | VAF 14/110 reads (13%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.973); called by muse, mutect2
- OTUD7A | c.2638C>T p.R880C (on ENST00000307050 / NM_001382637.1; = p.R873C on NM_130901.3) | Missense Mutation (SNP) | VAF 10/270 reads (4%) | SIFT tolerated, low confidence (0.08); PolyPhen possibly damaging (0.555); called by muse, mutect2
- PCLO | c.2500C>G p.P834A | Missense Mutation (SNP) | VAF 32/553 reads (6%) | SIFT tolerated, low confidence (0.05); PolyPhen benign (0.173); called by muse, mutect2
- PLCD1 | c.268G>T p.D90Y | Missense Mutation (SNP) | VAF 55/1146 reads (5%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.646); called by muse, mutect2
- PTPRT | c.512A>G p.K171R | Missense Mutation (SNP) | VAF 20/456 reads (4%) | SIFT tolerated (0.26); PolyPhen benign (0.232); called by muse, mutect2
- SRP54 | c.859A>G p.T287A | Missense Mutation (SNP) | VAF 22/342 reads (6%) | SIFT tolerated (0.64); PolyPhen benign (0.165); called by muse, mutect2
- TMEM200A | c.265C>T p.H89Y | Missense Mutation (SNP) | VAF 10/262 reads (4%) | SIFT deleterious (0.04); PolyPhen benign (0.041); called by muse, mutect2
- TMEM82 | c.433G>A p.G145S | Missense Mutation (SNP) | VAF 24/439 reads (5%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.979); called by muse, mutect2
- TPH1 | c.782A>T p.D261V | Missense Mutation (SNP) | VAF 39/796 reads (5%) | SIFT tolerated (0.14); PolyPhen probably damaging (0.998); called by muse, mutect2
- VPS35L | c.1633C>T p.Q545* | Nonsense Mutation (SNP) | VAF 23/289 reads (8%) | called by muse, mutect2
- ADGRV1 | c.5739C>T p.L1913= | Silent (SNP) | VAF 16/205 reads (8%) | catalogued as rs1445702123, COSV67997984; ClinVar: uncertain significance; called by muse, mutect2
- ATP8A2 | c.3462C>T p.G1154= | Silent (SNP) | VAF 16/169 reads (9%) | catalogued as rs1459224883; called by muse, mutect2
- FOXJ3 | c.1374G>A p.A458= | Silent (SNP) | VAF 21/417 reads (5%) | catalogued as rs528802214; called by muse, mutect2
- IGHM | c.450C>T p.R150= | Silent (SNP) | VAF 109/1081 reads (10%) | catalogued as rs782262928; called by muse, mutect2, varscan2
- MAEL | c.975A>G p.L325= | Silent (SNP) | VAF 18/398 reads (5%) | called by muse, mutect2
- MAGEB18 | c.339G>A p.S113= | Silent (SNP) | VAF 21/475 reads (4%) | catalogued as rs1305966996, COSV57464369; called by muse, mutect2
- TES | c.426G>T p.G142= | Silent (SNP) | VAF 13/119 reads (11%) | called by muse, mutect2, varscan2
- DMKN | c.1383+37G>T | Intron (SNP) | VAF 22/504 reads (4%) | called by muse, mutect2
- PITX2 | c.391-39T>G | Intron (SNP) | VAF 9/175 reads (5%) | called by muse, mutect2
- SAG | c.181+60G>A | Intron (SNP) | VAF 19/507 reads (4%) | catalogued as rs771097049, COSV68592662; called by muse, mutect2
- SLC25A12 | c.325+20A>G | Intron (SNP) | VAF 18/445 reads (4%) | called by muse, mutect2
